Somatic mutation profile of tumor specimen TCGA-DQ-7592-01A (aliquot TCGA-DQ-7592-01A-11D-2078-08) from TCGA case TCGA-DQ-7592, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; Tumor grade: G2; Age at diagnosis: 57.6 years (21,041 days).
Specimen TCGA-DQ-7592-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dd729369-9aef-449c-916a-fbdc8f000e22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DQ-7592-10A (Blood Derived Normal), aliquot TCGA-DQ-7592-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b03c0bc4-b44c-4c34-8424-adb81e0fabb8

The open-access MAF lists 83 somatic variants for this specimen: 60 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 21, Nonsense Mutation 6, Frame Shift Del 3, In Frame Del 2, Frame Shift Ins 2, 5'Flank 2, Translation Start Site 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.706T>G p.Y236D | Missense Mutation (SNP) | VAF 23/40 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587782289, CM1411658, COSV52672888, COSV52675514, COSV52783032; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ZEB1 | c.1576dup p.V526Gfs*3 | Frame Shift Ins (INS) | VAF 12/46 reads (26%) | catalogued as rs766305306; ClinVar: pathogenic; called by mutect2, varscan2
- ACKR2 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56177096; called by muse, mutect2
- ACOXL | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as rs778800133, COSV67733496; called by muse, mutect2, varscan2
- ARHGEF26 | c.1607A>T p.E536V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100726387; called by muse, mutect2
- ASTN2 | c.845T>A p.V282E | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); catalogued as COSV100524826; called by muse, mutect2, varscan2
- BBX | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1168225341, COSV57880212, COSV57881518, COSV57884048; called by muse, mutect2, varscan2
- BPI | c.25C>A p.P9T (on ENST00000262865; = p.P5T on NM_001725.3) | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.481); catalogued as COSV99480416; called by muse, mutect2, varscan2
- CACNA1C | c.3367C>T p.R1123C | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057518445, COSV100214148, COSV59696139; ClinVar: uncertain significance; called by muse, mutect2
- CBY2 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV60120340; called by muse, mutect2, varscan2
- CD68 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV99548736; called by muse, mutect2, varscan2
- CEP170 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100839486; called by muse, mutect2
- CLIC5 | c.995G>A p.R332H (on ENST00000185206 / NM_001370649.1; = p.R173H on NM_016929.5) | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1482226093, COSV99483822; called by muse, mutect2, varscan2
- CNGB1 | c.1943T>C p.I648T | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99201476; called by muse, mutect2, varscan2
- CREBBP | c.3729G>C p.E1243D | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); catalogued as COSV52131860, COSV52133128; called by muse, mutect2, varscan2
- CSH2 | c.336G>A p.W112* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100400151; called by muse, mutect2
- CSMD2 | c.8297C>A p.T2766N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.978); catalogued as COSV99586211; called by muse, mutect2, varscan2
- DISP1 | c.3605G>C p.C1202S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99449968; called by muse, mutect2, varscan2
- DNAH10 | c.6017C>T p.P2006L (on ENST00000409039; = p.P1945L on NM_207437.3) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68991921; called by muse, mutect2, varscan2
- DNAH11 | c.13006T>G p.W4336G | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100177236; called by muse, mutect2, varscan2
- DOLPP1 | c.76+1G>C p.X26_splice | Splice Site (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100588377, COSV59909950, COSV59910963; called by muse, mutect2, varscan2
- DRD5 | c.1408C>G p.P470A | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as COSV100431533; called by muse, mutect2, varscan2
- EPB41L2 | c.1066A>G p.I356V | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV61359076; called by muse, mutect2, varscan2
- EXOC3L2 | c.2111C>A p.P704Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99374452; called by muse, mutect2, varscan2
- FHOD1 | c.1718C>A p.S573* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99263851; called by muse, mutect2, varscan2
- FKBP6 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as rs782518033, COSV99333706, COSV99333956; called by muse, mutect2, varscan2
- FNTB | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1329044428, COSV99862754; called by mutect2, varscan2
- GNAO1 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.815); catalogued as rs1301302019, COSV99340698; called by muse, mutect2, varscan2
- GTF2E1 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 26/95 reads (27%) | catalogued as COSV99381736; called by muse, mutect2, varscan2
- IGHA1 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.098); catalogued as rs1170676105; called by muse, mutect2, varscan2
- KAT6B | c.2650G>C p.E884Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV99767376; called by muse, mutect2, varscan2
- LONP1 | c.1418A>G p.Y473C | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100638521; called by muse, mutect2, varscan2
- LRRC19 | c.460G>T p.G154C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV101195771; called by muse, mutect2, varscan2
- LRRC58 | c.678T>G p.Y226* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as rs373417962; called by muse, mutect2, varscan2
- MAP2 | c.2140C>G p.L714V | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs767208132, COSV99557945; called by muse, mutect2, varscan2
- NDN | c.617G>C p.R206T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as COSV100086152; called by muse, mutect2, varscan2
- OR2T11 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV100424706; called by muse, mutect2
- PEX3 | c.593A>G p.H198R | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100852084; called by muse, mutect2, varscan2
- PPFIBP2 | c.2121G>A p.E707= | Splice Region (SNP) | VAF 24/230 reads (10%) | catalogued as COSV100206024, COSV55078815; called by muse, mutect2
- RADIL | c.1416G>A p.W472* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV101271271; called by muse, mutect2
- RBCK1 | c.419C>G p.P140R (on ENST00000356286 / NM_031229.4; = p.P98R on NM_006462.6) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100675759; called by muse, mutect2, varscan2
- RBM5 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100762148; called by muse, mutect2, varscan2
- RBP3 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.95); catalogued as rs199801954; ClinVar: uncertain significance; called by muse, mutect2
- ROCK1 | c.325A>G p.K109E | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101296244; called by muse, mutect2, varscan2
- RPGRIP1L | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as rs374157187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RTCB | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV99321927; called by muse, mutect2, varscan2
- SGIP1 | c.955T>A p.S319T | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.351); catalogued as COSV99390530; called by muse, mutect2, varscan2
- SPG11 | c.1014G>T p.W338C | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99968068; called by muse, mutect2, varscan2
- SPTBN2 | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1425687730, COSV59458303; called by muse, mutect2, varscan2
- TCF20 | c.5371C>T p.R1791C | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1429923286, COSV59495764; called by muse, mutect2, varscan2
- TDRD1 | c.2099T>C p.V700A | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99314091; called by muse, mutect2, varscan2
- TRIM36 | c.2119G>A p.G707S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762451393, COSV99142258; called by muse, mutect2, varscan2
- TTF1 | c.1826_1828del p.K609del | In Frame Del (DEL) | VAF 8/44 reads (18%) | catalogued as rs765089719; called by pindel, varscan2
- UBXN6 | c.868G>T p.G290W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV100010839; called by muse, varscan2
- USH2A | c.5117G>A p.W1706* | Nonsense Mutation (SNP) | VAF 9/72 reads (13%) | catalogued as COSV100229218; called by muse, mutect2, varscan2
- AGPS | c.876del p.E293Kfs*18 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- FAT1 | c.9994dup p.T3332Nfs*15 | Frame Shift Ins (INS) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- HCN1 | c.2065del p.Q689Sfs*91 | Frame Shift Del (DEL) | VAF 6/61 reads (10%) | called by mutect2, pindel, varscan2
- PACC1 | c.122del p.G41Vfs*22 | Frame Shift Del (DEL) | VAF 31/238 reads (13%) | called by mutect2, pindel, varscan2
- TAF5L | c.248_274del p.D83_E91del | In Frame Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- CCDC8 | c.309C>T p.S103= | Silent (SNP) | VAF 19/156 reads (12%) | catalogued as rs1383575753, COSV100281884, COSV56775344; called by muse, mutect2, varscan2
- CDC42 | c.261A>G p.P87= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV100212502; called by muse, mutect2, varscan2
- DCAF4L2 | c.1182C>T p.Y394= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs375340661; called by muse, mutect2, varscan2
- DNAJB8 | c.555C>T p.S185= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV100048099; called by muse, mutect2, varscan2
- FBXL4 | c.952C>T p.L318= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100013862; called by muse, mutect2, varscan2
- FLT3 | c.2632C>T p.L878= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs1233032104, COSV99607413; called by muse, mutect2, varscan2
- GPNMB | c.1081C>T p.L361= (on ENST00000381990 / NM_001005340.2; = p.L349= on NM_002510.3) | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV51701189; called by muse, mutect2, varscan2
- H2BC15 | c.267C>T p.T89= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as rs762034527, COSV100356906; called by muse, mutect2, varscan2
- OR2T11 | c.186G>A p.Q62= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100424705; called by muse, mutect2
- OR52L1 | c.15T>C p.S5= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100176032; called by muse, mutect2, varscan2
- OTUD7A | c.1842G>A p.P614= (on ENST00000307050 / NM_001382637.1; = p.P607= on NM_130901.3) | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1241227024, COSV100191908; called by muse, mutect2
- PALM2AKAP2 | c.465T>C p.S155= (on ENST00000374531 / NM_001037293.2; = p.S187= on NM_053016.6) | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV100092610; called by muse, mutect2, varscan2
- PCDH8 | c.1002C>T p.R334= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs769828489, COSV100131225; called by muse, mutect2, varscan2
- PNMA8B | c.306C>T p.V102= | Silent (SNP) | VAF 29/221 reads (13%) | catalogued as COSV100885301; called by muse, mutect2, varscan2
- PTPRO | c.120C>T p.I40= | Silent (SNP) | VAF 22/101 reads (22%) | catalogued as rs1395692706, COSV55504429; called by muse, mutect2, varscan2
- RGS12 | c.2904C>T p.L968= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV100122569; called by muse, mutect2, varscan2
- SLC16A7 | c.1071T>G p.V357= | Silent (SNP) | VAF 19/92 reads (21%) | catalogued as COSV99676161; called by muse, mutect2, varscan2
- TENT5D | c.495C>T p.L165= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV100382556; called by muse, mutect2, varscan2
- ZFYVE9 | c.4041C>G p.L1347= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as rs145347233; called by muse, mutect2, varscan2
- ZNF134 | c.84G>A p.Q28= | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV101270698; called by muse, mutect2, varscan2
- ZNF831 | c.3624G>A p.A1208= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs759261413, COSV100925763; called by muse, mutect2, varscan2
- CES2 | chr16:66935508 T>C | 5'Flank (SNP) | VAF 66/141 reads (47%) | catalogued as rs747063141, COSV100399059; called by muse, mutect2, varscan2
- TTI2 | chr8:33513486 G>T | 5'Flank (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100659615; called by mutect2, varscan2
